Somatic mutation profile of tumor specimen 0DNE0L from CCDI case PBCBLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,834 days).
Specimen 0DNE0L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61ad9da8-3fbd-443f-9fd0-6bdd96f3d6e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNE0Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb78cba9-63a0-4567-9ac3-0eb1c9592279

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 1, Nonsense Mutation 1, Silent 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO1 | c.1189del p.I397Sfs*3 | Frame Shift Del (DEL) | VAF 100/441 reads (23%) | catalogued as COSV64595142; called by mutect2, pindel, varscan2
- HGFAC | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 121/677 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs775909849, COSV66977391; called by mutect2, varscan2
- PATJ | c.3838C>T p.R1280* | Nonsense Mutation (SNP) | VAF 24/500 reads (5%) | catalogued as rs769605018, COSV100219318; called by muse, mutect2
- TBX1 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 101/418 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746384751; called by muse, mutect2, varscan2
- YEATS2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs746535851, COSV59363702; called by muse, mutect2
- AHNAK | c.4074C>A p.D1358E | Missense Mutation (SNP) | VAF 156/504 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAPN12 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- VCPIP1 | c.3571T>C p.S1191P | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF512B | c.2255G>A p.C752Y | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A4 | c.4062A>G p.K1354= | Silent (SNP) | VAF 50/692 reads (7%) | called by muse, mutect2
- GTF2H3 | chr12:123633811 G>A | 5'Flank (SNP) | VAF 31/621 reads (5%) | catalogued as rs1454986002; called by muse, mutect2
- SIX5 | c.1610-19G>T | Intron (SNP) | VAF 67/222 reads (30%) | called by muse, mutect2, varscan2
